EXCEPTIONAL_RESPONDERS case ER-AC8A — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dca5fd31-71bc-4817-b87e-0acd55761e17

Demographics
Sex at birth: female; Year of birth: 1958; Vital status: Alive.

Diagnoses (1)
1. Large cell neuroendocrine carcinoma: ICD-O-3 morphology code: 8013/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Classification of tumor: metastasis; Age at diagnosis: 47.8 years (17,459 days); Year of diagnosis: 2005; AJCC pathologic stage: Stage IIIB; Days to last follow up: 2,129 days (5.8 years); Days to best overall response: 148 days; Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Carboplatin; Days to treatment start: 14 days; Days to treatment end: 140 days.
   Treatment given: Therapeutic agents: Etoposide; Days to treatment start: 15 days; Days to treatment end: 142 days.

Follow-up (1 entry)
- Days to follow up: 2,129 days (5.8 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 2,129 days (5.8 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-AC8A-NT1-A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-AC8A-NT1-A-1-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-AC8A-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE.
  Slide ER-AC8A-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 75; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
